Surgical pathology report (de-identified scan), TCGA case TCGA-D7-6525, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-6525-01A (Primary Tumor).

Examination: Histopathological examination

Material: 1. Total organ resection – oesophagus

TCGA – D7 – 6525

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis: **Cancer of the cardia**

Examination performed on:

Macroscopic description:

10.2 cm length of the gullet with a segment of the cardia sized (when cut open) 9.5 x 9.8 cm. Tumour sized 4.6 x 4.3 x 0.9 found in the cardiac region.

Distance from the proximal cut end 10.9 cm, from the distal cut end 4.4 cm.

The oesophagus mucous membrane, located proximally to the tumour, discoloured and smoothened over the length of 1.5 cm.

Microscopic description:

Adenocarcinoma tubulare partim mucocellulare (G3) (typus mixtus)

Infiltratio carcinomatosa telae adiposae perventricularis et parietis oesophagi.

The margin to the excision line uncertain at places (spec. A).

The other excision lines free of neoplastic lesions.

Foci of gastric metaplasia with features of dysplasia on the oesophagus wall

The lesions might have been the source of cancer development.

Stomach wall: Gastritic chronica (++) non activa (-).

Lymph nodes: Metastases carcinomatosae in lymphonodis (No VI/IX).

Infiltratio carcinomatosa telae perinodalis.

Histopathological diagnosis:

Adenocarcinoma tubulare partim mucocellulare cardiac. Tubular and partially mucocellular adenocarcinoma of the stomach cardia.

Metastases in lymphonodis (No VI/IX). Cancer metastases in the lymph nodes (No VI/IX).

(G3; pT2; pN2).

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 3711e08d-66cb-4a56-a3c9-2534e883f274 (TCGA-D7-6525.F06159FA-413A-4B46-B024-30F177D56EF6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).